Somatic mutation profile of tumor specimen TCGA-17-Z028-01A (aliquot TCGA-17-Z028-01A-01W-0746-08) from TCGA case TCGA-17-Z028, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10fb3ac7-3630-4738-b7d3-373e7be06037.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z028-11A (Solid Tissue Normal), aliquot TCGA-17-Z028-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a9a448f-2d94-48b1-8454-b0cd2cc09fe9

The open-access MAF lists 507 somatic variants for this specimen: 388 protein-altering or splice-affecting, 105 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 105, Nonsense Mutation 24, Frame Shift Del 14, Splice Site 12, RNA 6, Intron 4, Splice Region 3, 5'UTR 2, Frame Shift Ins 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.3266G>T p.C1089F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1401813809, COSV52703754, COSV52709920; called by muse, mutect2, varscan2
- ADAMTS16 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.89); catalogued as rs766063759, COSV99943307; called by muse, mutect2, varscan2
- ADAMTS16 | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1380263448, COSV56980181, COSV56991886; called by muse, mutect2
- ADAMTS20 | c.3077C>A p.A1026D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.726); catalogued as COSV67133621; called by muse, mutect2, varscan2
- AGBL5 | c.2002C>G p.P668A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.156); catalogued as rs369444845; called by muse, mutect2, varscan2
- ANK1 | c.1910C>A p.T637K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55878317; called by muse, mutect2, varscan2
- ANK2 | c.3219C>G p.F1073L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52185380; called by mutect2, varscan2
- ANXA7 | c.1102C>T p.L368F (on ENST00000372919 / NM_001320880.2; = p.L346F on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs907905604; called by muse, mutect2, varscan2
- ATN1 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1565570230, COSV99980857; called by muse, mutect2
- BBS2 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1199632846; called by muse, mutect2, varscan2
- BMPER | c.577-1G>C p.X193_splice | Splice Site (SNP) | VAF 61/496 reads (12%) | catalogued as COSV99779239; called by muse, mutect2, varscan2
- BSX | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545315; called by muse, mutect2, varscan2
- C9 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99661653; called by muse, mutect2
- CDC25C | c.1160T>C p.M387T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279365769; called by muse, mutect2, varscan2
- CDH7 | c.334C>A p.R112S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775706781, COSV59884116; called by muse, mutect2, varscan2
- CDK14 | c.1155G>C p.K385N (on ENST00000380050 / NM_001287135.2; = p.K367N on NM_012395.3) | Missense Mutation (SNP) | VAF 96/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56024014, COSV56030355, COSV56056025; called by muse, mutect2, varscan2
- CSMD3 | c.6032-1G>T p.X2011_splice (on ENST00000297405 / NM_001363185.1; = p.X1907_splice on NM_052900.3) | Splice Site (SNP) | VAF 13/92 reads (14%) | catalogued as COSV52216383; called by muse, mutect2, varscan2
- CSMD3 | c.4449G>C p.K1483N (on ENST00000297405 / NM_001363185.1; = p.K1379N on NM_052900.3) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV52320111; called by muse, mutect2, varscan2
- CUL9 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99334841; called by muse, varscan2
- CYTIP | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV51636218; called by muse, mutect2, varscan2
- DFFB | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1004333994; called by muse, mutect2
- DNAH7 | c.4029del p.A1344Lfs*2 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as COSV56768653; called by mutect2*, pindel, varscan2*
- DNAJC2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs751498127, COSV50785673; called by muse, mutect2
- DYNC1I1 | c.1104G>T p.W368C | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61457640; called by muse, mutect2, varscan2
- EPHA7 | c.2214G>T p.M738I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV65193844; called by muse, mutect2, varscan2
- FEM1B | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs751042625; called by muse, mutect2, varscan2
- FNIP1 | c.911G>T p.R304I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57198795; called by muse, mutect2, varscan2
- FOLH1 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV57051515; called by mutect2, varscan2
- GPR158 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as COSV66266405; called by muse, mutect2, varscan2
- GPR65 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs752555068, COSV99966026; called by muse, mutect2, varscan2
- GRIA2 | c.2422C>A p.L808I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52408146; called by muse, mutect2, varscan2
- GRIN2A | c.3567G>C p.K1189N | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58059723; called by muse, mutect2, varscan2
- GRM1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1372232374; called by muse, mutect2, varscan2
- HAUS5 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV52547167; called by muse, mutect2, varscan2
- HKDC1 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100664546; called by muse, mutect2, varscan2
- HNF4A | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100291140; called by muse, mutect2, varscan2
- HNRNPH2 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54510294; called by muse, mutect2, varscan2
- IRF6 | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.598); catalogued as BM1335179; called by muse, mutect2, varscan2
- ITPRID1 | c.2394C>A p.C798* | Nonsense Mutation (SNP) | VAF 57/88 reads (65%) | catalogued as rs779851488; called by muse, mutect2, varscan2
- JMJD1C | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs747987151; called by muse, mutect2, varscan2
- KCTD8 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63593703; called by muse, mutect2
- KDM2B | c.2327G>C p.R776P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as COSV65640404, COSV65643319, COSV65644480; called by muse, mutect2, varscan2
- KRT71 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs761759673; called by mutect2, varscan2
- KRTAP21-1 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100624939; called by muse, mutect2, varscan2
- LAMB4 | c.3915G>T p.A1305= | Splice Region (SNP) | VAF 29/108 reads (27%) | catalogued as COSV52727753; called by muse, mutect2, varscan2
- LMTK2 | c.2215A>C p.K739Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV52005671; called by muse, mutect2, varscan2
- LRRC4C | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV53426395, COSV99539654; called by muse, mutect2, varscan2
- LRRK1 | c.1388A>G p.K463R | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); catalogued as rs1487597371; called by muse, mutect2, varscan2
- LUC7L | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.83); catalogued as rs763299823, COSV53460440; called by muse, mutect2, varscan2
- MBIP | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs377276615; called by muse, mutect2, varscan2
- METTL23 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV57976053; called by muse, mutect2, varscan2
- MKRN3 | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100091396, COSV58810358; called by muse, mutect2, varscan2
- MRGPRX2 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as COSV61675010; called by muse, mutect2, varscan2
- MYH11 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV55551650; called by muse, mutect2, varscan2
- MYH2 | c.3459C>A p.S1153R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs142095822; called by mutect2, varscan2
- MYO18B | c.6218C>A p.S2073Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59137060; called by muse, mutect2, varscan2
- NAA25 | c.2260C>T p.L754F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs761746978; called by muse, mutect2
- NF1 | c.4077dup p.Q1360Sfs*20 (on ENST00000358273 / NM_001042492.3; = p.Q1360Sfs*14 on NM_000267.3) | Frame Shift Ins (INS) | VAF 20/121 reads (17%) | catalogued as COSV62223041; called by mutect2, pindel, varscan2
- NF1 | c.5645G>T p.C1882F (on ENST00000358273 / NM_001042492.3; = p.C1861F on NM_000267.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV62195751, COSV62225413; called by muse, mutect2
- NF1 | c.5647A>C p.T1883P (on ENST00000358273 / NM_001042492.3; = p.T1862P on NM_000267.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as CD000985; called by muse, mutect2
- NLRP3 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60223047; called by muse, mutect2, varscan2
- NPAP1 | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as COSV100275364, COSV61510575; called by muse, mutect2, varscan2
- NRXN1 | c.3134C>A p.A1045D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100453940, COSV58439070; called by muse, mutect2, varscan2
- OR13G1 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100687565; called by muse, mutect2, varscan2
- OR2A12 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 210/571 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV68821485; called by muse, mutect2, varscan2
- OR2M3 | c.214A>T p.M72L | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1206790934, COSV101513513; called by muse, varscan2
- OR2M5 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100822905, COSV63547133; called by muse, varscan2
- OR4K1 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as rs753284199; called by muse, mutect2
- OR4K5 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV60003307; called by muse, mutect2
- OR51V1 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.251); catalogued as COSV58316656; called by muse, mutect2, varscan2
- OR56B4 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV57204248; called by muse, mutect2, varscan2
- OR5B17 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.074); catalogued as rs763521418; called by muse, mutect2, varscan2
- OR6A2 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as rs111641381; called by muse, mutect2, varscan2
- PAPPA2 | c.4277del p.G1426Dfs*32 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV62811222; called by mutect2, pindel, varscan2
- PARVB | c.494G>C p.W165S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100115268; called by muse, mutect2, varscan2
- PAX3 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as CM950906, COSV60589510; called by muse, mutect2, varscan2
- PCDH10 | c.2912G>T p.S971I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52095441; called by muse, mutect2
- PCDHA11 | c.1097C>A p.T366K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56476068; called by muse, varscan2
- PCDHAC1 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV99165057; called by muse, mutect2, varscan2
- PDS5B | c.4175G>T p.R1392L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.199); catalogued as rs747642036; called by muse, mutect2, varscan2
- PIK3CG | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs781726578; called by muse, mutect2, varscan2
- PLCL1 | c.1692G>T p.M564I | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV70837559; called by muse, mutect2, varscan2
- PNLIPRP2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782705930, COSV53943140; called by muse, mutect2, varscan2
- PRAME | c.1491C>G p.D497E | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as rs374238684; called by muse, mutect2, varscan2
- PRDM9 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99690943; called by muse, mutect2, varscan2
- PRKAR1A | c.178-2A>T p.X60_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as CS093584, COSV62236702; called by mutect2, varscan2
- PRKAR1A | c.178-1G>T p.X60_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as CS113215, COSV62235898, COSV62236356; called by muse, mutect2, varscan2
- PRKCG | c.1561T>A p.Y521N | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54734426; called by muse, mutect2, varscan2
- PRPF6 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53876694; called by muse, mutect2
- PVRIG | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1385218964, COSV99066782; called by muse, mutect2
- PXDNL | c.3410C>A p.S1137* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV62484880; called by muse, mutect2, varscan2
- QRFPR | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57675341; called by muse, mutect2, varscan2
- RANBP2 | c.6275C>T p.T2092M | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs760931362, COSV51701084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGMB | c.781G>A p.V261M (on ENST00000513185 / NM_001366508.1; = p.V302M on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.25); catalogued as rs371130624, COSV57566269; called by muse, mutect2, varscan2
- RP1L1 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs755312869; called by muse, mutect2, varscan2
- RYR2 | c.11341C>T p.L3781F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759581727, COSV63677307; called by muse, mutect2, varscan2
- SALL4 | c.2771A>G p.N924S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs1213284489; called by muse, mutect2, varscan2
- SI | c.2873G>T p.R958L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as COSV52273192; called by muse, mutect2, varscan2
- SIGLEC8 | c.904del p.L302Cfs*19 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs748707537; called by mutect2, pindel, varscan2
- SKA3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100006344, COSV53435469; called by muse, mutect2, varscan2
- SLC2A3 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs146026720; called by muse, mutect2, varscan2
- SOX6 | c.1732G>C p.G578R (on ENST00000528429 / NM_001145819.2; = p.G551R on NM_017508.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs1270738759, COSV57059776; called by muse, mutect2, varscan2
- SPATA16 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.225); catalogued as COSV63532818, COSV63532986; called by muse, mutect2, varscan2
- SYT16 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs201294056, COSV70856512; called by muse, mutect2
- TENM2 | c.3870C>A p.Y1290* (on ENST00000518659 / NM_001122679.2; = p.Y1051* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV101318712; called by muse, mutect2, varscan2
- TENM3 | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as rs1179197424, COSV101305116; called by muse, mutect2
- TIAM1 | c.3329C>A p.P1110H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761556856; called by muse, mutect2, varscan2
- TMEM38B | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.058); catalogued as rs146683657; called by muse, mutect2, varscan2
- TMPRSS11E | c.576C>G p.I192M | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59517810; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3103G>T p.V1035L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs768586181; called by muse, mutect2, varscan2
- TRAF3 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1434703651; called by muse, varscan2
- TSPAN17 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV53780760; called by muse, mutect2, varscan2
- TTC3 | c.3428G>T p.R1143L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV61289865, COSV61293908; called by muse, mutect2, varscan2
- TTI1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100989553; called by muse, mutect2, varscan2
- TTLL2 | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99515001; called by muse, mutect2, varscan2
- UGT2A2 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.118); catalogued as COSV54144812; called by muse, varscan2
- UNC45B | c.2503C>G p.H835D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as rs1461526296; called by muse, mutect2, varscan2
- VCAM1 | c.1414C>G p.P472A | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54120198; called by muse, mutect2, varscan2
- WDR7 | c.4363G>T p.A1455S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.721); catalogued as COSV54366439, COSV99588361; called by muse, mutect2, varscan2
- XIRP2 | c.3007C>A p.Q1003K (on ENST00000628543; = p.Q1178K on NM_152381.6) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1203565470, COSV54680270, COSV99747321; called by muse, mutect2, varscan2
- XPO6 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58965191; called by muse, mutect2
- ZFPM2 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV65873087; called by muse, mutect2
- ZNF385D | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55772119; called by muse, mutect2, varscan2
- ZNF425 | c.683G>T p.R228I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV65202524; called by muse, mutect2, varscan2
- ZNF536 | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as rs1391146838; called by muse, mutect2, varscan2
- ZNF610 | c.1247C>A p.T416N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV58346732; called by muse, mutect2, varscan2
- ZNF654 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368258034; called by muse, mutect2, varscan2
- ABCA13 | c.9932A>C p.K3311T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ABCB7 | c.1064G>T p.R355I (on ENST00000373394 / NM_001271696.3; = p.R356I on NM_004299.6) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADAM11 | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1060T>A p.C354S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY5 | c.3699C>G p.Y1233* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1641G>T p.R547S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADGRG4 | c.6323C>T p.S2108F | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG6 | c.3132G>T p.M1044I | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AFAP1L1 | c.1532T>A p.M511K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- AKAP13 | c.5185C>T p.P1729S (on ENST00000394518 / NM_007200.5; = p.P1733S on NM_006738.6) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALKBH5 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- AMER2 | c.1159G>C p.D387H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD34A | c.1409G>T p.R470I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AOAH | c.976A>T p.R326* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.4484A>T p.E1495V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ARNT2 | c.147-1G>C p.X49_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- ASPHD2 | c.842C>G p.T281R | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ASTN1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 38/274 reads (14%) | called by muse, varscan2
- ATAD2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2
- ATP2B3 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 8/9 reads (89%) | called by mutect2, varscan2
- ATP9A | c.2746-2A>T p.X916_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- BNC1 | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- C1orf94 | c.1294G>T p.D432Y (on ENST00000488417 / NM_001134734.2; = p.D242Y on NM_032884.5) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- C2CD5 | c.1708G>T p.V570L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- C6 | c.2679C>A p.N893K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.902C>G p.T301S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CALR3 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK4 | c.751T>A p.F251I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CCN3 | c.1066A>G p.K356E | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- CD93 | c.1582A>G p.T528A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDH9 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CEP85 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP85 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- CES3 | c.1370_1373del p.K457Mfs*35 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- CHD3 | c.380A>C p.Q127P | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CHD8 | c.4763G>A p.R1588K (on ENST00000646647 / NM_001170629.2; = p.R1309K on NM_020920.4) | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CHL1 | c.2077G>T p.G693W (on ENST00000397491 / NM_001253387.1; = p.G709W on NM_006614.4) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHL1 | c.2078G>T p.G693V (on ENST00000397491 / NM_001253387.1; = p.G709V on NM_006614.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRM2 | c.823G>T p.V275F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CNTN5 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTN5 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CNTNAP2 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- COL11A1 | c.3686C>T p.P1229L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL6A6 | c.1480T>A p.S494T | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COQ3 | c.387-2A>T p.X129_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- CRYBG1 | c.2104A>T p.R702W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSDE1 | c.2216+1G>A p.X739_splice (on ENST00000358528 / NM_001007553.3; = p.X708_splice on NM_007158.6) | Splice Site (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- CSF2RB | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CSMD3 | c.10055G>C p.C3352S (on ENST00000297405 / NM_001363185.1; = p.C3183S on NM_052900.3) | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSN3 | c.30_31delinsT p.L11Wfs*3 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by pindel, varscan2*
- CTNND2 | c.3037C>A p.L1013I | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CUBN | c.7085T>C p.F2362S | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CUL9 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, varscan2
- CWH43 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CXorf21 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DCAF4L1 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, varscan2
- DCDC1 | c.4667C>G p.A1556G (on ENST00000597505 / NM_001367979.1; = p.A663G on NM_020869.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX11 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by mutect2, varscan2
- DDX24 | c.2543A>G p.Q848R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DEPDC1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKB | c.1576G>C p.G526R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIO3 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIP2C | c.4315G>T p.V1439L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- DMD | c.8560G>A p.E2854K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DMD | c.1424A>T p.E475V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- DNAH7 | c.4030del p.A1344Lfs*2 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- DRC1 | c.321del p.H107Qfs*9 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- DSE | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC2I1 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- DZIP3 | c.3175A>G p.K1059E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2AK3 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ELMOD1 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- EMID1 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ENAH | c.1646A>T p.Q549L (on ENST00000366844 / NM_001008493.3; = p.Q528L on NM_018212.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ENOX1 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- EPHA1 | c.2726G>A p.G909D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ETV5 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EXOC2 | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- EXTL3 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- FAM83B | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, varscan2
- FAT3 | c.3404A>G p.Y1135C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- FAT4 | c.2280G>T p.Q760H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBXO4 | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- FFAR1 | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FGF14 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2
- FGF14 | c.167G>T p.C56F | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.423); called by muse, mutect2
- FLG | c.5726G>A p.R1909K | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- FMO2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GABBR2 | c.1236G>A p.T412= | Splice Region (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- GABRA6 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GALNT13 | c.45_46del p.M16Vfs*5 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- GALNT7 | c.944T>A p.V315E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GH2 | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GJB5 | c.94del p.R32Afs*7 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- GNAI1 | c.878C>A p.S293* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- GON4L | c.5265G>C p.Q1755H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPA33 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GPR158 | c.2927T>A p.M976K | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- GPR174 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR83 | c.1178G>T p.R393M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- GREB1 | c.3374A>T p.H1125L | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GRIA4 | c.1832G>T p.C611F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GUCA2B | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GUCY2C | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- H4C8 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HACD2 | c.542_544delinsT p.S181Lfs*32 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by pindel, varscan2*
- HACL1 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAGH | c.289A>C p.T97P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.253); called by muse, mutect2
- HHIPL2 | c.1263G>T p.M421I | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- HIVEP2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXC8 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HPX | c.717G>T p.R239S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS3ST3A1 | c.1064_1065insA p.E356Gfs*19 | Frame Shift Ins (INS) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- HTT | c.3512C>G p.S1171C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- IFT80 | c.273_278del p.I92_S93del | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- IGF1R | c.3818G>T p.G1273V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IGKV1-17 | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KATNIP | c.2188C>G p.P730A | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- KCNH5 | c.588A>T p.K196N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KDM3A | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KIF4A | c.668G>C p.R223T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- KIF5C | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- KIR2DL1 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- KLHL1 | c.1026G>T p.M342I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLHL38 | c.1232G>A p.W411* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- KRT5 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMB3 | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- LANCL2 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LARS1 | c.2521del p.E841Kfs*41 (on ENST00000394434 / NM_020117.11; = p.E814Kfs*41 on NM_016460.3) | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- LGALS9 | c.758+1G>A p.X253_splice (on ENST00000395473 / NM_009587.3; = p.X221_splice on NM_002308.4) | Splice Site (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- LIPI | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP1 | c.1058A>T p.K353M (on ENST00000404816 / NM_206943.4; = p.K27M on NM_000627.4) | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGI2 | c.3390G>T p.R1130S | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MAP1B | c.6241G>T p.D2081Y | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEGF10 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MIS18BP1 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH3 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTARC2 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- NAV2 | c.5492G>C p.W1831S (on ENST00000396087 / NM_001244963.2; = p.W1775S on NM_145117.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAV3 | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NELL1 | c.542A>C p.N181T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NIPBL | c.3534G>C p.Q1178H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- NLGN4Y | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPAP1 | c.2764C>G p.P922A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- NPHS1 | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- NPR3 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- NUP214 | c.2265A>C p.K755N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OPRPN | c.681C>A p.N227K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- OR10Z1 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2T10 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- OR4K2 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR51A7 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- OR51F1 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR51F1 | c.284G>T p.W95L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- OR5B2 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ORC3 | c.2028C>T p.I676= | Splice Region (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- OSBP | c.2158G>C p.D720H | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OVCH1 | c.2103del p.G702Dfs*11 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- PABPC5 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.2417A>G p.Y806C | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAQR7 | c.964A>C p.T322P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); called by muse, varscan2
- PAWR | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- PCDH11X | c.3982C>A p.P1328T | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCDHA3 | c.315C>A p.H105Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- PCLO | c.11736A>C p.Q3912H | Missense Mutation (SNP) | VAF 77/576 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PDGFRA | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDHA2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- PKHD1L1 | c.8069C>A p.A2690D | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLB1 | c.3057+1G>T p.X1019_splice | Splice Site (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- PLBD1 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCH1 | c.1434+1G>T p.X478_splice (on ENST00000340059 / NM_001130960.2; = p.X490_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/97 reads (19%) | called by muse, varscan2
- PLXNA4 | c.2329C>A p.L777M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- POLR3B | c.2845G>C p.G949R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- POSTN | c.2425C>G p.Q809E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.814); called by muse, mutect2
- PPFIA2 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PPP1R3F | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- PRRC1 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSAT1 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PSENEN | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 80/123 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSKH2 | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, varscan2
- PSMD7 | c.431T>A p.V144D | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PTPRB | c.2908G>T p.E970* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- PTPRB | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRC | c.3677C>A p.A1226D | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PXN | c.1565A>G p.Y522C (on ENST00000228307 / NM_001080855.3; = p.Y488C on NM_002859.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PZP | c.3240G>T p.Q1080H | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RACGAP1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- RALGAPA1 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RBP7 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- RESF1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | called by mutect2, varscan2
- RFX4 | c.1274A>T p.Q425L (on ENST00000392842 / NM_213594.3; = p.Q331L on NM_032491.6) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- RHAG | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RHPN2 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 51/78 reads (65%) | called by muse, mutect2, varscan2
- RIMS2 | c.1160G>T p.R387M (on ENST00000666250 / NM_001348490.2; = p.R195M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF168 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROR2 | c.1500G>T p.Q500H | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- RP1L1 | c.5240A>T p.E1747V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- RSPH9 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RUBCNL | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- RYR2 | c.11779C>T p.P3927S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SBDS | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- SCN3A | c.5646C>A p.N1882K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3D19 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, varscan2
- SLC10A6 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A7 | c.202A>T p.M68L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLITRK2 | c.2287G>T p.V763F | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- SMG5 | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNX18 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SNX24 | c.190A>T p.R64W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPEF2 | c.5194A>T p.S1732C | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SPTA1 | c.2764G>T p.V922L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- STAP1 | c.504T>A p.Y168* | Nonsense Mutation (SNP) | VAF 58/198 reads (29%) | called by muse, mutect2, varscan2
- STAT3 | c.1172_1173del p.T391Kfs*36 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- SULT1B1 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SUN2 | c.1804T>A p.W602R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYT14 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TADA2A | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- TDRD1 | c.1932G>T p.L644F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TENM4 | c.4392C>G p.H1464Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TG | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TG | c.7923G>T p.E2641D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TLL1 | c.2834G>T p.G945V | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TM9SF4 | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2
- TMC4 | c.2057G>C p.R686P (on ENST00000617472 / NM_001145303.3; = p.R680P on NM_144686.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2
- TMTC3 | c.158A>C p.Q53P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TNC | c.2443A>G p.T815A | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNN | c.2995C>A p.Q999K | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- TNNI3K | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TPO | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRAF3IP3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- TRDV2 | c.40T>A p.W14R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TRIM51 | c.1028G>T p.W343L | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC6 | c.1274G>A p.W425* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- TSHZ2 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TSSK1B | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TSSK3 | c.679T>C p.S227P | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.884); called by muse, mutect2
- TTC21B | c.430-1G>C p.X144_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- TTF1 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- UNC79 | c.7261G>T p.G2421C (on ENST00000393151 / NM_001346218.2; = p.G2244C on NM_020818.5) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.9925G>A p.G3309R | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- VCAM1 | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VIRMA | c.5086G>T p.G1696* | Nonsense Mutation (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- XKR4 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- YIPF1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZFHX4 | c.6485T>A p.M2162K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZFPM2 | c.1253G>T p.S418I | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2
- ZNF195 | c.923T>A p.V308D (on ENST00000399602 / NM_001130520.3; = p.V236D on NM_007152.5) | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF284 | c.579T>A p.H193Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF292 | c.1741A>G p.K581E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ZNF366 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZNF385D | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF519 | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF607 | c.1281del p.K428Rfs*97 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- ZNF695 | c.113G>T p.R38I | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZNF804A | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZP4 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ABI3 | c.435C>T p.C145= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- ACAN | c.1995A>G p.P665= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1051326147; called by muse, mutect2, varscan2
- ACR | c.675C>T p.C225= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs577242211; called by muse, mutect2, varscan2
- ACTG1 | c.867C>A p.I289= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- AKAP8 | c.129C>G p.T43= | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- ANK2 | c.6465G>A p.L2155= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV52179280; called by muse, mutect2, varscan2
- CACNA2D1 | c.1524C>T p.P508= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CDON | c.3069A>T p.S1023= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- CLCN1 | c.1671G>A p.L557= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- CLEC9A | c.87T>C p.C29= | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- CMYA5 | c.4362A>T p.I1454= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- COL4A2 | c.4581C>T p.H1527= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- COLGALT2 | c.567G>T p.V189= | Silent (SNP) | VAF 13/143 reads (9%) | called by muse, mutect2
- CORIN | c.192C>A p.I64= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV56689629; called by muse, mutect2, varscan2
- CPA5 | c.1194C>A p.L398= | Silent (SNP) | VAF 40/108 reads (37%) | called by muse, varscan2
- CROCC | c.90G>A p.E30= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs771519997; called by muse, mutect2, varscan2
- CT83 | c.171T>C p.L57= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- CYP11B2 | c.126C>A p.P42= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CYP2C8 | c.1044T>A p.T348= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- DDX58 | c.807A>T p.G269= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- DNAH2 | c.528T>C p.G176= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- DNAJC2 | c.1281G>A p.E427= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- DPF3 | c.852C>T p.C284= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs780577141, COSV63499088; called by muse, mutect2, varscan2
- EPX | c.690C>T p.F230= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- EYA2 | c.699G>A p.A233= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs746177660, COSV57938778; called by muse, mutect2, varscan2
- FAIM | c.477G>C p.R159= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- FKBP1B | c.72G>C p.V24= | Silent (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- FMO4 | c.1311C>T p.I437= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs531809230; called by muse, mutect2, varscan2
- FRAS1 | c.10902C>A p.A3634= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- GHR | c.162C>A p.T54= | Silent (SNP) | VAF 126/284 reads (44%) | catalogued as CD972238; called by muse, mutect2, varscan2
- GOLGA5 | c.1725C>T p.T575= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- GPS2 | c.855C>T p.L285= | Silent (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- GRAMD1B | c.546C>T p.F182= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- GRIK1 | c.2046C>A p.P682= | Silent (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- H4C3 | c.99G>T p.P33= | Silent (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2
- HOXA1 | c.168C>A p.G56= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- IL7R | c.570C>A p.L190= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV57414807; called by muse, mutect2, varscan2
- KAT6A | c.5286C>T p.T1762= | Silent (SNP) | VAF 81/308 reads (26%) | called by muse, mutect2, varscan2
- KCNU1 | c.888C>T p.F296= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- KRTAP10-9 | c.423T>C p.C141= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as rs1425577167, COSV59966677; called by muse, mutect2, varscan2
- KRTAP11-1 | c.159G>A p.L53= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100190781; called by muse, mutect2, varscan2
- LAMA1 | c.2958C>T p.G986= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1413265131; called by muse, mutect2, varscan2
- LRBA | c.4752C>T p.S1584= | Silent (SNP) | VAF 81/530 reads (15%) | catalogued as rs1296801925; called by muse, mutect2, varscan2
- LRFN5 | c.723C>A p.P241= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs17854265, COSV53280821; called by muse, mutect2
- LRP1B | c.4899T>A p.A1633= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- LY9 | c.1152C>T p.S384= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs759198956, COSV99627012; called by muse, mutect2, varscan2
- MARCHF6 | c.2145C>T p.L715= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- MERTK | c.1158A>T p.A386= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- MROH7 | c.3330G>A p.K1110= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs763574773; called by muse, mutect2, varscan2
- MRTO4 | c.420G>T p.G140= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- MTUS2 | c.1050G>C p.G350= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV70916394; called by muse, mutect2, varscan2
- NCEH1 | c.1026T>A p.P342= (on ENST00000538775; = p.P302= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- NFATC4 | c.2562G>A p.P854= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs752364673, COSV51601085; called by muse, mutect2, varscan2
- NIPBL | c.5847G>A p.E1949= | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2
- NLRP3 | c.975G>T p.R325= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV60219416, COSV60229185; called by muse, mutect2, varscan2
- OR10S1 | c.741C>G p.G247= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs773075368; called by muse, mutect2, varscan2
- PAPPA | c.2046G>T p.L682= | Silent (SNP) | VAF 65/145 reads (45%) | called by muse, mutect2, varscan2
- PCDHB8 | c.2169G>T p.V723= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1470T>A p.S490= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1494G>T p.G498= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- PEAR1 | c.1938C>T p.P646= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1378611613, COSV99441594; called by muse, mutect2
- PKD2 | c.600C>T p.L200= | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2
- POMGNT2 | c.1560G>C p.V520= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- PPFIBP1 | c.36G>T p.A12= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV57298301; called by muse, mutect2
- PRDM9 | c.420G>A p.L140= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV99690700, COSV99690727; called by muse, mutect2, varscan2
- PRR16 | c.243T>C p.N81= (on ENST00000407149 / NM_001300783.2; = p.N58= on NM_016644.2) | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as rs1343291930; called by muse, mutect2, varscan2
- PTPRZ1 | c.4968G>T p.V1656= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV66434550, COSV66438747; called by muse, mutect2, varscan2
- ROBO1 | c.135C>A p.P45= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- RP1L1 | c.5457G>T p.A1819= | Silent (SNP) | VAF 83/176 reads (47%) | catalogued as COSV66757054; called by muse, mutect2, varscan2
- SACS | c.8058G>T p.L2686= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2
- SI | c.5163G>A p.Q1721= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100016288; called by muse, mutect2, varscan2
- SLC26A7 | c.429A>G p.Q143= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs764808239; called by muse, mutect2, varscan2
- SLC39A12 | c.2043C>G p.L681= (on ENST00000377369 / NM_001145195.2; = p.L644= on NM_152725.3) | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1221G>C p.L407= | Silent (SNP) | VAF 33/404 reads (8%) | catalogued as rs766762238; called by muse, mutect2
- SLCO1B1 | c.1992C>A p.V664= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- SMOX | c.1354C>T p.L452= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- SORL1 | c.744C>G p.V248= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99494973; called by muse, mutect2, varscan2
- STMN2 | c.240C>A p.S80= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99627055; called by muse, mutect2
- SYNE2 | c.3792C>T p.I1264= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs970964370; called by muse, mutect2, varscan2
- TBC1D32 | c.1191T>C p.T397= | Silent (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- TBX3 | c.27C>T p.V9= | Silent (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- TCTN2 | c.1602C>T p.L534= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs752527801; called by mutect2, varscan2
- TGFBRAP1 | c.2295C>T p.L765= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1463067832; called by muse, mutect2, varscan2
- TIE1 | c.750C>T p.F250= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- TLL2 | c.1143C>A p.I381= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.777G>T p.R259= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.3192T>G p.S1064= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- TPH2 | c.816C>T p.G272= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- TSEN2 | c.1146C>T p.V382= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- TTC24 | c.1542G>T p.G514= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV63997443; called by muse, mutect2, varscan2
- TTF2 | c.1926T>C p.H642= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- TXNDC2 | c.1146C>A p.I382= (on ENST00000306084 / NM_001098529.2; = p.I315= on NM_032243.6) | Silent (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- UGT2A2 | c.201T>C p.T67= | Silent (SNP) | VAF 28/207 reads (14%) | called by muse, varscan2
- VARS2 | c.48G>A p.L16= | Silent (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- VSTM1 | c.345G>C p.L115= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs994115553; called by muse, mutect2, varscan2
- WWTR1 | c.339C>T p.L113= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100640928; called by muse, mutect2, varscan2
- XRN1 | c.1869A>G p.E623= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ZFHX4 | c.10326C>A p.V3442= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.2415C>T p.A805= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- ZNF106 | c.1467C>G p.P489= | Silent (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- ZNF362 | c.1059C>T p.S353= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs368070032; called by muse, mutect2, varscan2
- ZNF366 | c.1206C>T p.F402= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV59216196, COSV59217612; called by muse, mutect2, varscan2
- ZNF461 | c.78G>T p.A26= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- ZNF577 | c.96C>T p.F32= | Silent (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.735G>T p.P245= (on ENST00000252463; = p.P300= on NM_032805.3) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52966951, COSV99373853; called by muse, mutect2, varscan2
- CDH2 | c.173-22586A>T | Intron (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240129992 G>A | 3'Flank (SNP) | VAF 4/21 reads (19%) | catalogued as rs1462434609, COSV100217114; called by muse, mutect2
- DCHS2 | n.4979G>T | RNA (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100601580; called by muse, mutect2, varscan2
- DCHS2 | n.3744C>G | RNA (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- FOLH1B | n.1013C>A | RNA (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- MIR376A2 | n.12G>T | RNA (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- MIR890 | n.9C>T | RNA (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- NRP2 | c.2440+9636C>T | Intron (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- OR2W5 | n.1241G>T | RNA (SNP) | VAF 25/117 reads (21%) | catalogued as rs1051364443; called by muse, mutect2, varscan2
- PAX6 | c.142-119A>G | Intron (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- PEAR1 | c.-2C>A | 5'UTR (SNP) | VAF 44/170 reads (26%) | called by muse, mutect2, varscan2
- PTN | c.-163G>T | 5'UTR (SNP) | VAF 7/70 reads (10%) | catalogued as COSV61964175; called by muse, mutect2
- SEC14L1 | c.*2537G>T | 3'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- TENM4 | c.-321+38430G>T | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53620264; called by muse, mutect2, varscan2
